Gene-level copy-number profile of tumor specimen TCGA-YF-AA3M-01A from TCGA case TCGA-YF-AA3M, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 57.8 years (21,097 days).
Specimen TCGA-YF-AA3M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a197f5be-b998-4bdd-8857-8f58b122d595.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YF-AA3M-10D (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/765df565-40f4-4a38-8a3f-8fb9edcae68a

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 200; copy number 3: 15,128; copy number 4: 15,723; copy number 5: 16,685; copy number 6: 4,153; copy number 7: 4,060; copy number 8: 341; copy number 9: 2,668; copy number 10: 95; copy number 11: 71; copy number 12: 615; copy number 16: 1; copy number 21: 27; copy number 24: 18; copy number 44: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YF-AA3M-01A-11D-A42D-01): tumor purity 0.68, ploidy 4.75, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 739 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:221,418,027–223,248,794, 28 genes, copy number 16–21 (within-gene range 5–21): EPHA4, TMEM256P2, AC079834.1, RPL23P5, AC068489.1, LLPHP3, HSPA9P1, RPL23AP28, PAX3, CCDC140, AC010980.1, CT75, Y_RNA, SGPP2, NANOGP2, RNU6-619P, GAPDHP49, FARSB, MOGAT1, RRAS2P2, AC104772.1, RPL31P17, ACSL3, ATG12P2, ACSL3-AS1, AC013476.1, KCNE4, RN7SL807P.
- chr5:58,198–39,721,513, 615 genes, copy number 12 (broad region; genes not listed).
- chr6:20,401,879–22,654,455, 25 genes, copy number 24–44 (within-gene range 7–44): E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1.
- chr20:31,257,664–32,858,751, 71 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
